CCDI case PBBMKI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/47f9ae36-2204-4e54-a053-b5e2a0463266

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Central neurocytoma: ICD-O-3 morphology code: 9506/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 18.8 years (6,863 days).

Biospecimens (3 samples)
- Sample 0DCS56: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCS59: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DCS5C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
